CCDI case PBCFNL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b54d35de-6141-49d2-bfb8-fdbdea249687

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Malignant tumor, small cell type: ICD-O-3 morphology code: 8002/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,264 days).

Biospecimens (3 samples)
- Sample 0DQZ3F: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQZ4C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQZ4P: Tissue type: Tumor; Specimen type: Solid Tissue.
